Somatic mutation profile of tumor specimen TCGA-14-0787-01A (aliquot TCGA-14-0787-01A-01D-1492-08) from TCGA case TCGA-14-0787, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 69.3 years (25,326 days).
Specimen TCGA-14-0787-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 667c51b9-3e9d-4e68-b273-95fdfa2e4ea1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-14-0787-10A (Blood Derived Normal), aliquot TCGA-14-0787-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b39c8875-5612-4ef5-9f9b-c78a72b01ea6

The open-access MAF lists 36 somatic variants for this specimen: 27 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 8, Nonsense Mutation 2, Frame Shift Del 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C2CD6 | c.179C>T p.T60M | Missense Mutation (SNP) | VAF 67/160 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs1398371869, COSV53792952; called by muse, mutect2, varscan2
- CARD11 | c.1823G>A p.R608H | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.781); catalogued as rs587778150, COSV62754807; ClinVar: not provided; called by muse, mutect2, varscan2
- CBLIF | c.404C>A p.P135H | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV57238504, COSV57239133; called by muse, mutect2, varscan2
- CLEC14A | c.1383C>A p.N461K | Missense Mutation (SNP) | VAF 119/265 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); catalogued as COSV60562213; called by muse, mutect2, varscan2
- DCHS1 | c.6650G>A p.R2217H | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs149822394; called by muse, mutect2, varscan2
- DENND1B | c.1156G>A p.D386N | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.466); catalogued as rs756328709, COSV52463232; called by muse, mutect2, varscan2
- FAM124B | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs149161165, COSV66271729; called by muse, mutect2, varscan2
- GPR179 | c.3221A>G p.H1074R (on ENST00000621958; = p.H1073R on NM_001004334.4) | Missense Mutation (SNP) | VAF 55/109 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as rs754835795; called by muse, mutect2, varscan2
- GTDC1 | c.590T>A p.V197D | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); catalogued as COSV53991990; called by muse, mutect2, varscan2
- HMCN1 | c.13189C>T p.R4397W | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs776115129, COSV54890766; called by muse, mutect2, varscan2
- INPP5E | c.1167G>C p.E389D | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV65496124; called by muse, mutect2, varscan2
- KCNK18 | c.200G>T p.R67I | Missense Mutation (SNP) | VAF 48/65 reads (74%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV57971482; called by muse, mutect2, varscan2
- MRC1 | c.2101C>T p.R701* | Nonsense Mutation (SNP) | VAF 94/134 reads (70%) | catalogued as rs1470400951; called by muse, mutect2, varscan2
- MYO1A | c.2452C>G p.Q818E | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT tolerated (0.54); PolyPhen benign (0.036); catalogued as COSV55653092; called by muse, mutect2, varscan2
- OR4N2 | c.880G>A p.V294M | Missense Mutation (SNP) | VAF 36/256 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.145); catalogued as COSV60050804; called by muse, mutect2, varscan2
- PYGL | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1445713979, COSV53585192; called by muse, mutect2, varscan2
- RLIM | c.1739G>A p.G580D | Missense Mutation (SNP) | VAF 75/93 reads (81%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV60325984; called by muse, mutect2, varscan2
- RYR2 | c.6281G>A p.G2094D | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1215753475, COSV63677274; called by muse, mutect2, varscan2
- SEC14L5 | c.889G>A p.V297M | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as COSV52037720; called by muse, mutect2, varscan2
- SF3A3 | c.1123G>T p.E375* | Nonsense Mutation (SNP) | VAF 42/119 reads (35%) | catalogued as COSV65955720; called by muse, mutect2, varscan2
- SMOC1 | c.433C>A p.P145T | Missense Mutation (SNP) | VAF 74/172 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62759787, COSV62760353; called by muse, mutect2, varscan2
- TBC1D31 | c.715C>T p.H239Y | Missense Mutation (SNP) | VAF 58/166 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs1185711371, COSV54865136; called by muse, mutect2, varscan2
- TYK2 | c.2578C>T p.R860C | Missense Mutation (SNP) | VAF 39/49 reads (80%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); catalogued as rs1405594069, COSV53386132; called by muse, mutect2, varscan2
- VCAN | c.9584G>A p.R3195Q | Missense Mutation (SNP) | VAF 35/295 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145625752; called by muse, mutect2, varscan2
- VPS54 | c.2072G>A p.R691H | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs779279818, COSV55439446; called by muse, mutect2, varscan2
- AC011455.2 | c.1367del p.R457Gfs*64 | Frame Shift Del (DEL) | VAF 35/137 reads (26%) | called by mutect2, pindel, varscan2
- TIAL1 | c.325del p.T109Qfs*20 | Frame Shift Del (DEL) | VAF 23/36 reads (64%) | called by mutect2, pindel, varscan2
- C2CD6 | c.1233C>T p.G411= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as COSV53793383; called by muse, mutect2, varscan2
- FRYL | c.3078G>A p.L1026= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as COSV51944391; called by muse, mutect2, varscan2
- NAV3 | c.5598G>A p.P1866= (on ENST00000397909 / NM_001024383.2; = p.P1844= on NM_014903.6) | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as rs200326115, COSV57072849, COSV57089458; called by muse, mutect2, varscan2
- NFIC | c.966G>A p.S322= | Silent (SNP) | VAF 41/264 reads (16%) | catalogued as rs745783582, COSV59411288; called by muse, mutect2, varscan2
- NPAP1 | c.522C>T p.D174= | Silent (SNP) | VAF 46/108 reads (43%) | catalogued as rs368120585, COSV100274980; called by muse, mutect2, varscan2
- OR8J3 | c.747G>A p.T249= | Silent (SNP) | VAF 49/129 reads (38%) | catalogued as rs529152876, COSV56880098, COSV56881389; called by muse, mutect2, varscan2
- SCNN1A | c.1116C>T p.G372= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as rs567003433, COSV57434973; called by muse, mutect2, varscan2
- USO1 | c.1926A>G p.K642= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as COSV53706119; called by muse, mutect2, varscan2
- SSPOP | n.7105G>T | RNA (SNP) | VAF 9/39 reads (23%) | catalogued as COSV50487086; called by muse, mutect2, varscan2
